Surgical pathology report (de-identified scan), TCGA case TCGA-IQ-7632, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University of Miami, specimen TCGA-IQ-7632-01A (Primary Tumor).

[page 1 of 7]
AGE/SEX:

SPECIMEN ID:

- A. NECK, NOS - LEFT NECK DISSECTION LEVEL 1,
- B. NECK, NOS - LEFT NECK DISSECTION LEVEL 2 AND 3,
- C. NECK, NOS - LEFT SUBMENTAL TRIANGLE NECK DISSECTION,
- D. MANDIBLE, NOS - LEFT COMPOSITE RESECTION, E. MANDIBLE, NOS - PROXIMAL MANDIBLE FS,
- F. MANDIBLE, NOS - DISTAL MANDIBLE FS, G. MOUTH - ANTERIOR FLOOR OF MOUTH,
- H. MOUTH - LEFT RETROMOLAR TRIGONE, I. MOUTH - POSTERIOR FLOOR OF MOUTH,
- J. MOUTH - LEFT ANTERIOR BUCCAL MUCOSA, K. MOUTH - LEFT BUCCAL MUCOSA POSTERIOR,
- L. MUCOUS MEMBRANE, NOS - ADDITIONAL GINGIVAL BUCCAL MUCOSA NOT A MARGIN,
- M. MOUTH - LEFT GINGIVAL BUCCAL SOLSTICE, N. MOUTH - LEFT LINGUAL ALVEOLAR RIDGE,
- O. TONGUE - TONGUE, P. MOUTH - PTERYGOID,
- Q. MANDIBLE, NOS - ADDITIONAL MANDIBLE BONE AND TISSUES, R. TOOTH - # 23 TOOTH

A. LEFT NECK DISSECTION, LEVEL 1:

Lymph nodes (2); negative for tumor.

Parotid gland; no specific pathologic changes.

B. LEFT NECK DISSECTION, LEVELS 2 AND 3:

Lymph nodes (25); negative for tumor.

C. LEFT COMPOSITE RESECTION:

Lymph nodes (3); negative for tumor.

D. LEFT COMPOSITE RESECTION:

[page 2 of 7]
*** FINAL DIAGNOSIS *** (Continued)

Invasive, well-differentiated squamous cell carcinoma; 5.5 cm.

Tumor invades up to mandibular bone.

Margins negative for tumor.

Osteonecrosis.

E. PROXIMAL MANDIBLE:

No malignancy seen.

F. DISTAL MANDIBLE:

No malignancy seen.

G. ANTERIOR FLOOR OF MOUTH:

No malignancy seen.

H. LEFT RETROMOLAR TRIGONE:

No malignancy seen.

I. POSTERIOR FLOOR OF MOUTH:

No malignancy seen.

J. LEFT ANTERIOR BUCCAL MUCOSA:

No malignancy seen.

K. LEFT BUCCAL MUCOSA POSTERIOR:

No malignancy seen.

L. ADDITIONAL GINGIVAL BUCCAL MUCOSA (NOT A MARGIN):

[page 3 of 7]
*** FINAL DIAGNOSIS *** (Continued)

No malignancy seen.

M. LEFT GINGIVAL BUCCAL SOLSTICE:

No malignancy seen.

N. LEFT LINGUAL ALVEOLAR RIDGE:

No malignancy seen.

O. TONGUE:

No malignancy seen.

P. PTERYGOID:

No malignancy seen.

Q. ADDITIONAL LEFT MANDIBULAR BONE AND TISSUE:

Bone with osteonecrosis.

No evidence of malignancy.

R. TOOTH #23:

Gross only.

CLINICAL HISTORY-

PRE-OP DX: Not provided

PROCEDURE: Not provided

RELEVANT CLINICAL HX: Not provided

[page 4 of 7]
GROSS DESCRIPTION:

- A. Received in formalin and labeled "Left neck dissection Level 1" is a fibroadipose tissue which measures 5.0 x 4.0 x 3.5 cm. Sectioning reveals a salivary gland which measures 3.0 x 4.0 x 1.5 cm. Largest lymph node measures 1.5 x 1.5 x 1.0 cm. Sections submitted as follows:

Cassette #1: Largest lymph node bisected
Cassette #2: One lymph node bisected
Cassette #3: Representative section of salivary gland

- B. Received in formalin and labeled "Left neck dissection, levels 2 & 3" is a fibroadipose tissue fragment which measures 7.5 x 5.0 x 3.0 cm. There is a stitch at one end. The largest lymph node from the half with the stitch measures 2.5 x 1.5 x 1.0 cm. The internal surface of that lymph node has focal areas of hemorrhage and areas that are brown to white. Largest lymph node opposite to the stitch measures 1.5 x 1.0 x 0.7 cm. Cassettes submitted as follows:

Cassettes #1-10: Lymph nodes from the section from the suture stitch
Cassettes #1&2: Representative sections from largest lymph node
Cassette #3: Four possible lymph nodes
Cassette #4: Four possible lymph nodes
Cassette #5: Four possible lymph nodes
Cassette #6: One lymph node bisected
Cassette #7: Three possible lymph nodes
Cassette #8: One lymph node bisected
Cassette #9: One lymph node bisected
Cassette #10: One lymph node bisected
Cassettes #11&12: Section opposite to the suture
Cassette #11: Five possible lymph node
Cassette #12: One lymph node bisected

- C. Received in formalin and labeled "Left submental neck dissection" is a fibroadipose tissue which measures 4.0 x 2.5 x 1.5 cm. Largest lymph node measures 1.0 x 0.7 x 0.5 cm. Sections submitted as follows:

Cassette #1: Three possible lymph nodes
Cassette #2: Largest lymph node bisected

- D. Received in formalin and labeled "Left composite resection" is a right mandible with fibroadipose tissue connected, teeth and buccal mucosa. Specimen measures 7.5 x 4.0 x 3.0 cm. There are four teeth. One molar, two premolar, one _____. There is a large exophytic mass located both on the medial and lateral surfaces of the specimen. It

[page 5 of 7]
GROSS DESCRIPTION: (Continued)

measures 5.5 x 3.5 x 4.0 cm. The lesion appears to invade the mandible and invade the teeth. Sections submitted as follows:

Cassettes #1&2: Composite section of anterior bone margin in composite

Cassette #1: Superior end

Cassette #2: Inferior end

Cassettes #3&4: Composite section of posterior bony margin

Cassette #3: Superior end

Cassette #4: Inferior end

Cassette #5: Mucosal margin from the lateral buccal surface on the posterior aspect of the specimen

Cassettes #6&7: Composite section of representative section of lesion

Cassette #6: Mandible with tumor on medial surface

Cassette #7: Mandible with tumor on lateral surface

Cassette #8: Representative section of tumor with mandible and buccal mucosa on lateral surface

Cassette #9: Representative section of tumor with buccal mucosa on lateral surface

Cassettes #10&11: Composite section of tumor with mandible and attached soft tissue

Cassette #10: Medial surface

Cassette #11: Tumor with lateral surface

Cassette #12: Additional representative section of tumor

Note: Cassettes #1,2,3,4,6,7,8,10,11 are submitted for decalcification

- E. Received fresh and labeled "Proximal mandible" is a soft tissue fragment which measures 0.5 x 0.4 x 0.2 cm. Tissue is tan/white and hard. Submitted in toto in one cassette for frozen section.
- F. Received fresh and labeled "Distal mandible" is a tan/white, hard tissue fragment which measures 0.5 x 0.5 x 0.3 cm. Submitted in toto in one cassette for frozen section.
- G. Received fresh and labeled "Anterior floor of mouth" is a tan/pink, soft tissue fragment which measures 3.0 x 0.5 x 0.5 cm. Submitted in toto in one cassette for frozen section.
- H. Received fresh and labeled "Left retromolar trigone" is a tan/pink, soft tissue measuring 2.0 x 0.5 x 0.5 cm. Submitted in toto in one cassette for frozen section.
- I. Received fresh and labeled "Posterior floor of mouth" is a tan/pink, soft tissue fragment which measures 3.0 x 0.4 x 0.4 cm. Submitted in toto in one cassette for frozen section.

[page 6 of 7]
GROSS DESCRIPTION: (Continued)

- J. Received fresh and labeled "Left anterior buccal mucosa" is a tan/pink, soft tissue fragment which measures 3.5 x 0.5 x 0.3 cm. Submitted in toto in one cassette for frozen section.
- K. Received fresh and labeled "Left buccal mucosa posterior" are three fragments of tan/pink, soft tissue fragments which measures 1.0 x 1.0 x 0.5 cm in aggregate. Submitted in toto in one cassette for frozen section.
- L. Received in formalin and labeled "Additional gingival buccal mucosa, not a margin" is a soft tissue, tan tissue fragment which measures 1.4 x 0.5 x 0.2 cm. Submitted in toto in one cassette.
- M. Received fresh and labeled "Left gingival buccal solstice" is a tan/pink, soft tissue fragment which measures 1.8 x 0.3 x 0.3 cm. Submitted in toto in one cassette for frozen section.
- N. Received fresh and labeled "Left lingual alveolar ridge" is tan/pink, soft tissue fragment which measures 1.0 x 0.5 x 0.3 cm. Submitted in toto in one cassette for frozen section.
- O. Received fresh and labeled "Tongue" is a tan/pink, soft tissue fragment which measures 0.5 x 0.5 x 0.3 cm. Submitted in toto in one cassette for frozen section.
- P. Received fresh and labeled "Pterygoid" is a tan/white firm tissue fragment which measures 1.2 x 0.6 x 0.5 cm. Submitted in toto in one cassette for frozen section.
- Q. Received in formalin and labeled "Additional left mandibular bone and tissue" are multiple fragments of bone with connective soft tissue measuring 2.4 x 1.5 x 0.6 cm in aggregate. Submitted in toto in two cassettes after decalcification.
- R. Received in formalin and labeled "I23 tooth" is an incisor which measures 2.3 X 0.5 X 0.5 cm. Tooth has some soft tissue attached and significant yellow on the internal surface but is otherwise unremarkable. Gross description only.

[page 7 of 7]
OPERATING ROOM CONSULT [REDACTED]

E) PROXIMAL MANDIBLE [REDACTED]
FSDX: NO MALIGNANCY SEEN

F) DISTAL MANDIBLE [REDACTED]
FSDX: NO MALIGNANCY SEEN

G) ANTERIOR FLOOR OF MOUTH [REDACTED]
FSDX: NO MALIGNANCY SEEN

H) LEFT RETROMOLAR TRIGONE [REDACTED]
FSDX: NO MALIGNANCY SEEN

I) POSTERIOR FLOOR OF MOUTH [REDACTED]
FSDX: NO MALIGNANCY SEEN.

[REDACTED] CONCURS

J) LEFT ANTERIOR BUCCAL MUCOSA [REDACTED]
FSDX: NO MALIGNANCY SEEN

K) LEFT BUCCAL MUCOSA POSTERIOR
FSDX: NO MALIGNANCY SEEN

M) LEFT GINGIVAL BUCCAL SOSTICE [REDACTED]
FSDX: NO MALIGNANCY SEEN

N) LEFT LINGUAL ALVEOLAR RIDGE [REDACTED]
NO MALIGNANCY SEEN

O) TONGUE [REDACTED]
FSDX: NO MALIGNANCY SEEN

P) PTERYGOID [REDACTED]
FSDX: NO MALIGNANCY SEEN

Source: NCI Genomic Data Commons file 3c24d13b-9bce-4ddc-9e84-43d4c0871a40 (TCGA-IQ-7632.4E2A322D-2323-40BC-BB05-55F4CCEA9298.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).